Gene-level copy-number profile of tumor specimen TCGA-B6-A0IK-01A from TCGA case TCGA-B6-A0IK, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 63.4 years (23,150 days).
Specimen TCGA-B6-A0IK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.e0a41bf9-0af4-4a94-9b08-724a938ae4ae.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B6-A0IK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 821 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2ffd2f9e-f438-4fc2-ae4c-2a3cd973addb

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 2: 14,519; copy number 3: 1,444; copy number 4: 38,687; copy number 5: 645; copy number 6: 3,936; copy number 7: 192; copy number 8: 24; copy number 9: 37; copy number 10: 59; copy number 13: 25; copy number 14: 40; copy number 15: 19; copy number 16: 6; copy number 21: 47; copy number 23: 66; copy number 24: 6; copy number 25: 28; copy number 32: 7; copy number 34: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B6-A0IK-01A-12D-A059-01): tumor purity 0.52, ploidy 1.83, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:52,401,008–52,579,237, 8 genes (within-gene range 0–2): BAP1, PHF7, SEMA3G, TNNC1, NISCH, STAB1, NT5DC2, SMIM4.
- chr3:52,551,846–52,560,707, 2 genes: RNU6-856P, RNU6ATAC16P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 310 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:62,110,524–63,234,911, 18 genes, copy number 15: NARS1P2, AC104852.1, AC023095.1, NKAIN3, AC018861.2, AC018861.1, AC090577.1, XRCC6P4, SRPK2P, AC120042.1, GGH, AC120042.2, TTPA, AC011978.1, YTHDF3-AS1, YTHDF3, AC011978.2, RN7SL135P.
- chr8:79,520,145–80,080,775, 13 genes, copy number 14 (within-gene range 4–14): AC100870.1, RPL3P9, STMN2, AC016240.1, HEY1, LINC01607, AC036214.1, RNU7-85P, AC036214.4, MRPS28, AC036214.3, AC036214.2, AC009686.2.
- chr8:91,542,924–91,907,619, 2 genes, copy number 9 (within-gene range 8–9): AC103409.1, RN7SKP231.
- chr8:100,133,351–102,124,907, 56 genes, copy number 10–13 (within-gene range 2–13): FBXO43, POLR2K, SPAG1, Y_RNA, AC025647.1, Y_RNA, RNF19A, AP001574.1, AP003472.1, MIR4471, AP003472.2, AP000424.1, AP000424.2, ANKRD46, GAPDHP62, SNX31, AP001205.1, RNU6-1092P, PABPC1, MIR7705, RNU6ATAC41P, Y_RNA, RPS20P23, RNU4-83P, RPS26P6, Metazoa_SRP, AC027373.1, YWHAZ, RN7SL685P, FLJ42969, AP003469.2, AP003469.1, RN7SKP249, AP003469.3, ZNNT1, ZNF706, AP001330.4, AP001330.2, LINC02844, AP001330.5, AP001330.1, RNU7-67P, AP001330.3, NACA4P, DUXAP2, LINC02845, RN7SL563P, AP001208.1, AP001207.3, GRHL2, AP001207.2, AP001207.1, NCALD, AP000426.1, AP001329.1, PDCL3P2.
- chr8:112,222,928–113,436,939, 1 gene, copy number 24 (within-gene range 2–24): CSMD3.
- chr8:113,376,669–119,424,434, 45 genes, copy number 14–25: AC107890.1, AC055788.2, AC055788.1, AC103993.1, Y_RNA, AC064802.1, AC025881.1, CARS1P2, TRPS1, AF178030.1, LINC00536, RNA5SP276, AC090994.1, AC105177.1, EIF3H, UTP23, RAD21, RAD21-AS1, MIR3610, AARD, SLC30A8, RN7SL228P, AC027419.1, AC027419.2, RN7SL826P, AC084114.1, AP002848.1, MED30, RPS10P16, EXT1, SAMD12, AC023590.1, SAMD12-AS1, RPS26P35, TNFRSF11B, RNU6-12P, AC107953.1, COLEC10, AC107953.2, MAL2, MAL2-AS1, MIR548AZ, AC021733.4, AC021733.1, CCN3.
- chr8:123,851,987–127,742,951, 68 genes, copy number 21–34 (within-gene range 2–34) (broad region; genes not listed).
- chr8:127,795,962–127,890,720, 2 genes, copy number 34: MIR1204, AC084123.1.
- chr15:82,531,653–82,757,206, 15 genes, copy number 14 (within-gene range 4–14): DNM1P38, AC245033.4, RPS17, AC245033.1, AC245033.2, CPEB1, CPEB1-AS1, AP3B2, AC105339.4, AC105339.1, ACTG1P17, AC105339.5, AC105339.3, AC105339.6, SNHG21.
- chr15:84,748,592–85,139,145, 10 genes, copy number 13 (within-gene range 4–13): ZNF592, AC012291.2, ALPK3, AC012291.1, SLC28A1, AC087468.2, RNU6-339P, RNU6-796P, AC087468.1, PDE8A.
- chr17:59,707,192–62,065,278, 72 genes, copy number 10–23 (broad region; genes not listed).
- chr17:64,477,785–64,542,461, 6 genes, copy number 16 (within-gene range 6–16): POLG2, ATP5MFP4, DDX5, MIR3064, MIR5047, CEP95.
- chr20:39,655,325–39,815,097, 2 genes, copy number 10: AL132981.1, AL118523.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
